Somatic mutation profile of tumor specimen TCGA-KN-8421-01A (aliquot TCGA-KN-8421-01A-11D-2310-10) from TCGA case TCGA-KN-8421, project TCGA-KICH (Kidney Chromophobe). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 48.0 years (17,524 days).
Specimen TCGA-KN-8421-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce60ed8b-b1cf-4186-baa1-c7b69310abe1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KN-8421-11A (Solid Tissue Normal), aliquot TCGA-KN-8421-11A-01D-2310-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/588e14ca-ed4b-4e9a-a995-a6b683221b71

The open-access MAF lists 19 somatic variants for this specimen: 11 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 6, Frame Shift Del 2, Splice Site 2, 5'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATG2A | c.5227G>A p.G1743S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs746563475; called by muse, mutect2, varscan2
- B3GALT5 | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.987); catalogued as rs144752439; called by muse, mutect2, varscan2
- CCDC85A | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs775195592, COSV101339464, COSV68154085; called by muse, mutect2
- CFAP44 | c.1890+1G>A p.X630_splice | Splice Site (SNP) | VAF 80/96 reads (83%) | catalogued as COSV99870223; called by muse, mutect2, varscan2
- LRRC41 | c.400del p.S134Pfs*116 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | catalogued as rs1557715031, COSV58440688; called by pindel, varscan2
- NLRP7 | c.2237G>A p.R746H (on ENST00000340844 / NM_206828.3; = p.R718H on NM_139176.3) | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.743); catalogued as rs1370606415, COSV60178265; called by muse, mutect2, varscan2
- SEC14L3 | c.54+1G>A p.X18_splice | Splice Site (SNP) | VAF 6/24 reads (25%) | catalogued as rs755264057; called by muse, mutect2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 9/60 reads (15%) | catalogued as rs767420916; called by mutect2, varscan2
- WFDC5 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.991); catalogued as rs370436377; called by muse, mutect2, varscan2
- ZC3H12A | c.628T>C p.F210L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100897758; called by muse, mutect2, varscan2
- KBTBD6 | c.1785G>T p.W595C | Missense Mutation (SNP) | VAF 106/118 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARC | c.1143C>T p.P381= | Silent (SNP) | VAF 23/45 reads (51%) | catalogued as rs755164360, COSV63078129; called by muse, mutect2, varscan2
- DNASE2B | c.477A>T p.P159= | Silent (SNP) | VAF 31/34 reads (91%) | called by muse, mutect2, varscan2
- PRPF40A | c.204C>T p.G68= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as rs760295511; called by muse, mutect2, varscan2
- SCN3A | c.2502C>A p.L834= | Silent (SNP) | VAF 11/221 reads (5%) | called by muse, mutect2
- STX6 | c.702A>G p.Q234= | Silent (SNP) | VAF 24/27 reads (89%) | catalogued as rs746309226; called by muse, mutect2, varscan2
- VSTM1 | c.117T>A p.V39= | Silent (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- ACKR4 | c.*43T>C | 3'UTR (SNP) | VAF 47/85 reads (55%) | catalogued as COSV99392534; called by muse, mutect2, varscan2
- RHBG | chr1:156367763 del GTTGGTCCC | 5'Flank (DEL) | VAF 53/69 reads (77%) | called by mutect2, pindel, varscan2
